Surgical pathology report (de-identified scan), TCGA case TCGA-HZ-A8P1, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-HZ-A8P1-01A (Primary Tumor).

[page 1 of 2]
Sex: Male
DOB:

Collected:
Received:
Reported:

SURGICAL PATHOLOGY REPORT

DIAGNOSIS

DIAGNOSIS:

- A. Distal pancreas, spleen, distal pancreatectomy, splenectomy:
Pancreatic ductal adenocarcinoma arising in a background of intraductal pancreatic mucinous neoplasm with severe dysplasia.
AJCC stage p T2 N0. See tumor characteristics.
Resection margin negative for malignancy.
Five lymph nodes negative for metastatic adenocarcinoma. (0/5).

PANCREAS (EXOCRINE):

Specimen

Tail of pancreas
Spleen

Procedure

Partial pancreatectomy, pancreatic tail

Tumor Site

Pancreatic tail

Tumor Size

Greatest dimension: 5.0 cm
+ Additional dimensions: 4.0- x 3.2 cm

Histologic Type

Ductal adenocarcinoma

Histologic Grade (ductal carcinoma only)

G1: Well differentiated

Microscopic Tumor Extension

Tumor is confined to pancreas

Margins

Margin uninvolved by carcinoma in situ / high-grade dysplasia

Margin uninvolved by invasive carcinoma

Inked Pancreatic resection margin

Treatment Effect (applicable to carcinomas treated with neoadjuvant therapy)

No prior treatment

Lymph-Vascular Invasion

Not identified

Perineural Invasion

Present

Pathologic Staging (pTNM)

Primary Tumor (pT)

pT2: Tumor limited to the pancreas, more than 2 cm in greatest dimension

Regional Lymph Nodes (pN)

pN0: No regional lymph node metastasis

Comment: 2 lymph nodes show involvement by direct extension of tumor.

Number of Lymph Nodes Examined

5

Number of Lymph Nodes Involved

0

Distant Metastasis (pM)

Not applicable

+ Additional Pathologic Findings

Other (specify): IPMN with high grade dysplasia

+ Ancillary Studies

None

+ Clinical History

Not specified

+ Comment(s)

None

ICD O-3

Adenocarcinoma, duct NOS
850013

Site Pancreas tail C25.2

4/2/14

[page 2 of 2]
Electronic Signature:**CLINICAL INFORMATION****CLINICAL HISTORY:**

Preoperative Diagnosis: Abdominal mass, pancreatitis, bowel obstruction

Postoperative Diagnosis:

Symptoms/Radiologic Findings:

SPECIMENS:

Proximal margin of distal pancreas-resection with frozen section

SPECIMEN DATA**GROSS DESCRIPTION:**

Specimen is received fresh for frozen section in a single container labeled a distal pancreatectomy specimen with attached spleen. The specimen is comprised of distal portion of pancreas (9.0 x 9.0 x 3.5 cm), and spleen (12.0 x 8.0 x 4.0 cm). The proximal pancreatic margin is received stapled. The staple line is removed the underlying parenchyma is inked blue. Bulging from the inferior aspect of the pancreas is a 7.0 x 5.0 x 3.5 cm previously ruptured cyst. Cyst contents are not present. The inner lining is pink-tan and wrinkled. The pancreas is inked black. A representative section from the proximal pancreatic margin submitted for frozen section with residual entirely resubmitted for permanent section. Further sectioning through the pancreas reveals a 5.0 x 4.0 x 3.2 cm gray-white indurated mass that approaches to within less than 0.1 cm of the superior, inferior, anterior, and posterior pancreatic surfaces. Additionally, this mass abuts the aforementioned cyst. The cysts grossly communicates with the main pancreatic duct. No normal appearing pancreatic parenchyma is identified. This mass approaches to within 1.5 cm of the splenic hilum which is grossly uninvolved. On section and palpation, two possible peripancreatic lymph nodes are identified near the stapled margin. They are 0.5 and 0.7 cm in greatest dimension. No lymph nodes are identified at the splenic hilum. The spleen weighs 154 grams and features an intact purple-gray capsule. Sectioning reveals a beefy red glistening cut surface with punctate white pulp. No masses or lesions are identified. Representative sections are submitted in cassettes A1-16 labeled as follows: 1 - frozen section residue; 2 - mass to superior pancreas, perpendicular; 3 - mass to superior pancreas and splenic artery, perpendicular; 4 - mass to inferior pancreas, perpendicular; 5 - mass to anterior pancreas, perpendicular; 6 - mass to posterior pancreas, perpendicular; 7 - mass to include adjacent cyst wall and pancreatic duct; 8-9 - additional mass to include adjacent cyst wall; 10 - additional mass; 11 - additional cyst wall to include inked surface, perpendicular; 12 - two whole possible intraparenchymal lymph nodes; 13-16 - spleen. Additionally, a yellow-green and blue cassette are submitted for each labeled

INTRA-OPERATIVE CONSULTATION:

FROZEN SECTION DIAGNOSIS: 'Tumor not definitively seen at proximal inked margin' per Dr.

Source: NCI Genomic Data Commons file 1333d60a-dd05-4bba-93a7-45aab754340b (TCGA-HZ-A8P1.80B04A2F-D419-4E6A-80C3-605BAE94D96A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).